Somatic mutation profile of tumor specimen TCGA-DX-A8BV-01A (aliquot TCGA-DX-A8BV-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.5 years (21,005 days).
Specimen TCGA-DX-A8BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f8c9e0b-c1f6-4b4c-9520-aeec0db1e1b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BV-10A (Blood Derived Normal), aliquot TCGA-DX-A8BV-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69861679-14b7-4cf3-ba5d-9c1b5298cea9

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 45/66 reads (68%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL6 | c.1766A>G p.H589R (on ENST00000379240; = p.H614R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1202306203, COSV99732261; called by muse, mutect2
- APLP2 | c.1645A>C p.K549Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99599364; called by muse, mutect2, varscan2
- C9 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99661509; called by muse, mutect2
- CCL15 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs138739843; called by muse, mutect2, varscan2
- CEACAM5 | c.1811C>G p.S604C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV99703674; called by muse, mutect2, varscan2
- CRYBA4 | c.569G>T p.S190I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697718, COSV61321256; called by muse, mutect2, varscan2
- ERICH3 | c.2537A>T p.E846V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100443077; called by muse, mutect2, varscan2
- GABRD | c.370A>C p.T124P | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101059499; called by muse, mutect2, varscan2
- HMCN1 | c.12229G>A p.V4077I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV99622302; called by muse, mutect2, varscan2
- IDH1 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100575828; called by muse, mutect2, varscan2
- IGF2BP3 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99324822; called by muse, mutect2, varscan2
- KCNA5 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.73); catalogued as COSV99363500; called by muse, mutect2, varscan2
- KIF3B | c.1973A>G p.E658G | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100996279; called by muse, mutect2
- KLRC2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV101122625; called by muse, mutect2, varscan2
- LAMC2 | c.3397C>T p.Q1133* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99916864; called by muse, mutect2, varscan2
- LILRB5 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV100299934; called by muse, mutect2, varscan2
- LRP5 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99591122; called by muse, mutect2, varscan2
- MAGEL2 | c.1958C>G p.P653R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV100045633; called by muse, mutect2, varscan2
- NRIP1 | c.3169G>C p.D1057H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012029; called by muse, mutect2, varscan2
- NRIP1 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV100012030; called by muse, mutect2, varscan2
- OR10C1 | c.213G>C p.E71D (on ENST00000622521; = p.E69D on NM_013941.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as rs977356543, COSV101010777; called by mutect2, varscan2
- OR14K1 | c.454G>C p.A152P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99314892; called by muse, mutect2, varscan2
- P2RX7 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as rs149639375, COSV55855706; called by muse, mutect2, varscan2
- PCDHA12 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs1266651704, COSV56480427; called by muse, mutect2, varscan2
- PCDHGA4 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV99528127; called by muse, mutect2, varscan2
- PLCXD3 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100124968; called by muse, mutect2, varscan2
- PRDM15 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1161002451, COSV99519101; called by muse, mutect2
- RAPSN | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.491); catalogued as COSV100099911; called by muse, mutect2
- RARB | c.1131C>G p.I377M (on ENST00000383772 / NM_001290216.2; = p.I370M on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99978933; called by muse, mutect2, varscan2
- SARDH | c.1358C>G p.P453R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100898249; called by muse, mutect2, varscan2
- SCN2A | c.3655C>A p.L1219M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99329567; called by muse, mutect2, varscan2
- SIRPB2 | c.995T>G p.M332R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100708333; called by muse, mutect2, varscan2
- SLC10A7 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99389818; called by muse, mutect2, varscan2
- SPATA31E1 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.075); catalogued as COSV100349701; called by muse, mutect2, varscan2
- SRCIN1 | c.3413C>T p.P1138L (on ENST00000621492; = p.P1104L on NM_025248.3) | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs748117292; called by muse, mutect2, varscan2
- SULT1E1 | c.485T>A p.M162K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV99894585; called by muse, mutect2, varscan2
- TM7SF2 | c.536T>A p.L179H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99659475; called by muse, mutect2
- TMEM199 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99134645; called by muse, mutect2, varscan2
- TTC30B | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as COSV101282755; called by muse, mutect2
- ZNF175 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99219208, COSV99219871; called by muse, mutect2, varscan2
- ATRX | c.2979_2982del p.K993Nfs*9 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | called by mutect2, pindel, varscan2
- FRG2C | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IGKV1-27 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.3158_3163del p.P1053_K1054del | In Frame Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- YY1 | c.383_411del p.E128Afs*10 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ARAP1 | c.3819C>T p.V1273= (on ENST00000393609 / NM_001040118.2; = p.V1028= on NM_015242.4) | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs775177903, COSV100501397; called by muse, mutect2, varscan2
- CNTNAP5 | c.2757G>A p.T919= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs993689069, COSV70475303; called by muse, mutect2, varscan2
- DHX37 | c.2829C>T p.S943= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs760244891, COSV100438880; called by muse, mutect2, varscan2
- IGHJ1 | c.51A>T p.S17= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs578092570; called by muse, mutect2, varscan2
- IGHV2-70 | c.51C>A p.V17= | Silent (SNP) | VAF 94/122 reads (77%) | catalogued as rs529818160; called by muse, mutect2, varscan2
- KCNA5 | c.366C>T p.V122= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99363503; called by muse, mutect2, varscan2
- KRT12 | c.294G>A p.G98= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs775479919, COSV99288712; called by muse, mutect2, varscan2
- MAPKBP1 | c.1020G>A p.A340= (on ENST00000456763 / NM_001128608.2; = p.A334= on NM_014994.3) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs762867127, COSV52958379; called by muse, mutect2, varscan2
- OR56A3 | c.576C>T p.S192= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100289936, COSV100290251; called by muse, mutect2
- PCDHGA1 | c.261G>A p.A87= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV65296567; called by muse, mutect2, varscan2
- PLEKHG4B | c.2997A>G p.E999= (on ENST00000283426; = p.E1355= on NM_052909.5) | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV99359572; called by muse, mutect2
- TNFRSF12A | c.48G>A p.G16= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV50188318; called by muse, mutect2
- UBE2O | c.3270G>T p.L1090= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100039088; called by muse, mutect2
- ZFR | c.2796C>T p.L932= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs772605934, COSV99415169; called by muse, mutect2, varscan2
- ZFYVE21 | c.396A>G p.K132= | Silent (SNP) | VAF 70/116 reads (60%) | catalogued as COSV99157359; called by muse, mutect2, varscan2
- RPL31P57 | n.142G>T | RNA (SNP) | VAF 12/81 reads (15%) | catalogued as rs1555643031; called by muse, mutect2, varscan2
